Somatic mutation profile of tumor specimen TARGET-10-PANVDV-09A (aliquot TARGET-10-PANVDV-09A-01D) from TARGET case TARGET-10-PANVDV, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 7.5 years (2,740 days).
Specimen TARGET-10-PANVDV-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f464f9a2-849c-4c5d-888f-4b90f980f28d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PANVDV-14A (Bone Marrow Normal), aliquot TARGET-10-PANVDV-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/89e256a1-af64-43b3-97a7-7e68ad335d0d

The open-access MAF lists 34 somatic variants for this specimen: 29 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 24, Frame Shift Del 3, Silent 3, Frame Shift Ins 1, 5'UTR 1, Splice Region 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.37G>T p.G13C | Missense Mutation (SNP) | VAF 11/56 reads (20%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs121434595, COSV54736386, COSV54736476, COSV54736550; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PAX5 | c.77T>G p.V26G | Missense Mutation (SNP) | VAF 56/83 reads (67%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs926053251, COSV63904854, COSV63909409; called by muse, mutect2, varscan2
- ADCY5 | c.2150A>G p.D717G | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); catalogued as rs1335631982; called by muse, mutect2
- ATP6V0A2 | c.1015C>A p.R339S | Missense Mutation (SNP) | VAF 20/37 reads (54%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.866); catalogued as COSV57748635; called by muse, mutect2, varscan2
- CDH12 | c.2046del p.V683* | Frame Shift Del (DEL) | VAF 16/88 reads (18%) | catalogued as rs1296145829; called by mutect2, pindel, varscan2
- CLDN1 | c.631G>A p.V211M | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.992); catalogued as rs147881276, COSV55044256; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GRID1 | c.2011C>G p.L671V | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs1283337135; called by muse, mutect2, varscan2
- KCNA5 | c.602G>A p.R201H | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.8); catalogued as rs765380398, COSV52904032, COSV99363787; called by muse, mutect2, varscan2
- KCNJ8 | c.677G>A p.R226H | Missense Mutation (SNP) | VAF 18/112 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.017); catalogued as rs762588905, COSV53716118, COSV99557432; called by muse, mutect2, varscan2
- MSI1 | c.809A>T p.Y270F | Missense Mutation (SNP) | VAF 32/92 reads (35%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.855); catalogued as COSV99981446; called by muse, mutect2, varscan2
- NBEAL1 | c.3518G>A p.R1173H | Missense Mutation (SNP) | VAF 36/136 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); catalogued as rs761736185, COSV71375315; called by muse, mutect2, varscan2
- PCGF3 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 8/140 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1388151810; called by muse, mutect2
- RAD54L2 | c.1511G>T p.C504F | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56581157, COSV56582278; called by muse, mutect2, varscan2
- RFPL4A | c.752G>A p.R251H | Missense Mutation (SNP) | VAF 30/438 reads (7%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.903); catalogued as rs775264890, COSV70455589; called by muse, mutect2
- RFPL4AL1 | c.752G>A p.R251H | Missense Mutation (SNP) | VAF 13/126 reads (10%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.797); catalogued as rs778969067, COSV59112650; called by muse, mutect2, varscan2
- WSCD1 | c.1664C>T p.T555M | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.959); catalogued as rs555182532, COSV100496388; called by muse, mutect2, varscan2
- CDH19 | c.320G>C p.R107T | Missense Mutation (SNP) | VAF 25/145 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.683); called by muse, mutect2, varscan2
- CR2 | c.1465C>G p.P489A | Missense Mutation (SNP) | VAF 19/128 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- DDX3X | c.571del p.M191Wfs*29 (on ENST00000399959; = p.M192Wfs*29 on NM_001356.5) | Frame Shift Del (DEL) | VAF 13/33 reads (39%) | called by mutect2, pindel*, varscan2*
- DNM1 | c.439G>T p.D147Y | Missense Mutation (SNP) | VAF 18/158 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- OR2A14 | c.8G>A p.G3D | Missense Mutation (SNP) | VAF 14/103 reads (14%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PREX2 | c.2097del p.H700Mfs*3 | Frame Shift Del (DEL) | VAF 10/76 reads (13%) | called by mutect2, pindel, varscan2
- RAB26 | c.740A>G p.E247G | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.347); called by muse, mutect2, varscan2
- TBL1XR1 | c.940G>T p.V314F | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- TBL1XR1 | c.327_328insT p.A110Cfs*35 | Frame Shift Ins (INS) | VAF 7/39 reads (18%) | called by mutect2, pindel, varscan2
- TRAF3IP2 | c.1386+3_1386+4insGCCA | Splice Region (INS) | VAF 15/88 reads (17%) | called by mutect2, pindel, varscan2
- TXLNB | c.1258A>T p.I420F | Missense Mutation (SNP) | VAF 31/195 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- UTY | c.497T>A p.I166N | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- ZNF208 | c.2719C>T p.H907Y | Missense Mutation (SNP) | VAF 26/118 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- MAB21L1 | c.42A>G p.K14= | Silent (SNP) | VAF 23/66 reads (35%) | called by muse, mutect2, varscan2
- MGST1 | c.333C>T p.V111= | Silent (SNP) | VAF 33/149 reads (22%) | catalogued as rs202065205; called by muse, mutect2, varscan2
- MYH2 | c.705C>T p.N235= | Silent (SNP) | VAF 11/81 reads (14%) | catalogued as rs201018335, COSV55434048; ClinVar: likely benign; called by muse, mutect2, varscan2
- EIF4G2 | c.1300-56A>T | Intron (SNP) | VAF 16/28 reads (57%) | called by muse, mutect2, varscan2
- SIM1 | c.-39G>A | 5'UTR (SNP) | VAF 19/145 reads (13%) | called by muse, mutect2, varscan2
